MMRF case MMRF_1550 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a73e53e9-65df-44c1-ae6a-2a6f659878e5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.8 years (26,235 days); ISS stage: III; Days to last known disease status: 1,276 days (3.5 years); Days to last follow up: 1,276 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 23 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 204 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 30 days; Days to treatment end: 51 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 58 days; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 310 days; Days to treatment end: 708 days (1.9 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 709 days (1.9 years); Days to treatment end: 827 days (2.3 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 838 days (2.3 years); Days to treatment end: 1,232 days (3.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 58.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.533 mg/dL; Immunoglobulin G 5.48 g/L; Immunoglobulin A 4.49 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 5.73 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 9.46 mmol/L.
- Day 86 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.203 mg/dL; Hemoglobin 7.81 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 16.4 mmol/L.
- Day 178 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 3.16 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.19 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 6.9 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 12.5 mmol/L.
- Day 280 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.618 mg/dL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 9.08 mmol/L.
- Day 366 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Hemoglobin 7.75 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 10.2 mmol/L.
- Day 421 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Hemoglobin 7.94 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 10.1 mmol/L.
- Day 533 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Hemoglobin 7.63 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 11.9 mmol/L.
- Day 617 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Hemoglobin 7.87 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 12.3 mmol/L.
- Day 736 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 20.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.746 mg/dL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 59 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 11.4 mmol/L.
- Day 799 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 198 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.917 mg/dL; Lactate Dehydrogenase 7.97 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 18.4 mmol/L.
- Day 916 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Hemoglobin 7.25 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 16.4 mmol/L.
- Day 1,028 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.152 mg/dL; Hemoglobin 6.08 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 7.9 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.23 mmol/L; Albumin 30 g/L; Total Protein 6.2 g/dL; Glucose 18.9 mmol/L.
- Day 1,084 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.088 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 11.1 mmol/L.
- Day 1,168 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Hemoglobin 8 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 14.9 mmol/L.
- Day 1,276 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.102 mg/dL; Hemoglobin 8.49 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 15.4 mmol/L.

Other clinical attributes
- Day -5: Weight: 127 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Lymphoma.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1550_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1550_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
